Gene-level copy-number profile of tumor specimen TCGA-N8-A4PI-01A from TCGA case TCGA-N8-A4PI, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinosarcoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Age at diagnosis: 71.9 years (26,270 days).
Specimen TCGA-N8-A4PI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.488a8931-3428-4074-896a-c75dde5851dc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-N8-A4PI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/11ade847-8cb1-4bf9-829c-8b11bc061ba0

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 956; copy number 2: 3,835; copy number 3: 12,708; copy number 4: 36,876; copy number 5: 257; copy number 6: 2,420; copy number 7: 2,686; copy number 9: 44; copy number 11: 34.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N8-A4PI-01A-21D-A28Q-01): tumor purity 0.78, ploidy 3.87, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 78 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:33,750,679–34,343,711, 24 genes, copy number 9: PRSS3, UBE2R2-AS1, TRBV29OR9-2, UBE2R2, Y_RNA, RNU4ATAC11P, UBAP2, SNORD121B, SNORD121A, OSTCP8, RN7SKP114, AL354989.1, DCAF12, TUBB4BP2, AL354989.2, UBAP1, RPL35AP2, AL353662.2, RNA5SP282, AL353662.1, KIF24, RNU2-50P, SERPINH1P1, NUDT2.
- chr10:66,926,036–68,212,017, 20 genes, copy number 9 (within-gene range 4–9): LRRTM3, AL139240.1, RPL7AP51, MIR7151, AKR1B10P1, RPL21P92, DNAJC12, RNU6-1250P, RN7SL394P, DNAJC19P1, AL133551.1, RNU6-523P, RPL12P8, SIRT1, HERC4, RPS3AP38, RN7SL220P, POU5F1P5, MYPN, RN7SKP202.
- chr10:74,151,202–74,709,963, 1 gene, copy number 11 (within-gene range 6–11): ADK.
- chr10:74,371,535–75,431,588, 31 genes, copy number 11: RPSAP6, RAB5CP1, AC022540.1, MRPL35P3, Y_RNA, NDUFA8P1, POLR3DP1, FAM32CP, AC063962.1, KAT6B, AC018511.2, AC018511.1, DUSP29, AC018511.6, PPIAP13, DUSP13, SAMD8, RPS26P42, VDAC2, COMTD1, ZNF503-AS1, RPL39P25, HMGA1P5, AC010997.3, AC010997.1, SPA17P1, ZNF503, ZNF503-AS2, AC010997.5, AC010997.4, AC010997.2.
- chr10:75,450,081–75,552,553, 2 genes, copy number 11: AC010997.6, MIR606.

Autosomal genes at a single copy (total copy number 1): 149. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
